Somatic mutation profile of tumor specimen TCGA-DH-A66B-01A (aliquot TCGA-DH-A66B-01A-11D-A29Q-08) from TCGA case TCGA-DH-A66B, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.4 years (19,156 days).
Specimen TCGA-DH-A66B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc485977-9a0f-49b5-a4ea-e3e40942e10c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A66B-10A (Blood Derived Normal), aliquot TCGA-DH-A66B-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59e23406-0926-4902-85a4-a10ba00c686e

The open-access MAF lists 48 somatic variants for this specimen: 41 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Frame Shift Del 7, Silent 6, In Frame Del 4, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABL2 | c.1430A>T p.E477V (on ENST00000502732 / NM_007314.4; = p.E462V on NM_005158.5) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61021720; called by muse, mutect2, varscan2
- AC006059.2 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1402203837, COSV59605952; called by muse, mutect2, varscan2
- APIP | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as COSV53508913; called by muse, mutect2, varscan2
- CHAF1B | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58441951; called by muse, mutect2, varscan2
- CHRM3 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776861962, COSV55080950; called by muse, mutect2, varscan2
- COBL | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs184520448, COSV54361743; called by muse, mutect2, varscan2
- COQ5 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV56020989; called by muse, mutect2, varscan2
- CRISPLD1 | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.972); catalogued as rs1329981562, COSV51553861; called by muse, mutect2, varscan2
- CYP3A4 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199908125, COSV60500893; called by muse, mutect2, varscan2
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2
- DNAH11 | c.9521G>C p.R3174T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV60987165; called by muse, mutect2
- FCRL2 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV63835479; called by muse, mutect2, varscan2
- IFIH1 | c.2287T>G p.F763V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55130945; called by muse, mutect2, varscan2
- INSRR | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63878026; called by muse, mutect2, varscan2
- ITPR3 | c.1229A>G p.E410G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765845561, COSV65415725; called by muse, mutect2, varscan2
- KIF2B | c.1852C>A p.Q618K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV52136708; called by muse, mutect2, varscan2
- MAP2K5 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV51624407; called by muse, mutect2, varscan2
- NOTCH1 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as CM159398, COSV53065420, COSV53102266; called by muse, mutect2, varscan2
- OTX2 | c.602G>T p.C201F (on ENST00000408990 / NM_172337.3; = p.C209F on NM_021728.4) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59768023; called by muse, mutect2, varscan2
- PCDH15 | c.5855C>G p.S1952C | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs781440414, COSV57410931; called by muse, mutect2, varscan2
- PKHD1 | c.6869G>C p.W2290S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61898427; called by muse, mutect2, varscan2
- PLIN1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55585579; called by muse, mutect2, varscan2
- PTPRZ1 | c.6262C>T p.Q2088* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV101100686, COSV66447466; called by muse, mutect2, varscan2
- RGS3 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs371153692, COSV58286427; called by muse, mutect2, varscan2
- RGS3 | c.618_620del p.F207del (on ENST00000350696 / NM_001282923.2; = p.F95del on NM_017790.4) | In Frame Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs762481352; called by pindel, varscan2
- SCRIB | c.2865_2868del p.P956Afs*18 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs1554635930; called by mutect2, pindel, varscan2
- TRAIP | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs745919040, COSV58917263; called by muse, mutect2, varscan2
- WDR17 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV54586214; called by muse, mutect2, varscan2
- WDR24 | c.661T>A p.F221I (on ENST00000248142; = p.F159I on NM_032259.4) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV50207328; called by muse, mutect2, varscan2
- AIFM1 | c.1449-7_1449-3del | Splice Region (DEL) | VAF 47/67 reads (70%) | called by mutect2, pindel, varscan2
- ARID1A | c.606_607del p.H203Rfs*196 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- ATF2 | c.1141_1143del p.E381del | In Frame Del (DEL) | VAF 33/118 reads (28%) | called by mutect2, pindel, varscan2
- ATRX | c.2648_2651del p.Q883Rfs*21 | Frame Shift Del (DEL) | VAF 67/103 reads (65%) | called by mutect2, pindel, varscan2
- DNAJA2 | c.1140_1141del p.G381Lfs*8 | Frame Shift Del (DEL) | VAF 140/456 reads (31%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.3080del p.V1027Afs*27 | Frame Shift Del (DEL) | VAF 43/261 reads (16%) | called by mutect2, pindel, varscan2
- KMT2A | c.1862_1864del p.S621del | In Frame Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- PPL | c.3514_3516del p.E1172del | In Frame Del (DEL) | VAF 24/236 reads (10%) | called by mutect2, pindel
- RXFP2 | c.1920_1921del p.F642Yfs*5 | Frame Shift Del (DEL) | VAF 39/101 reads (39%) | called by mutect2, pindel, varscan2
- TP53 | c.959dup p.K321Efs*16 | Frame Shift Ins (INS) | VAF 76/121 reads (63%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1016_1017del p.R339Nfs*5 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by pindel, varscan2
- MORC2 | c.2127T>G p.V709= (on ENST00000397641 / NM_001303256.3; = p.V647= on NM_014941.3) | Silent (SNP) | VAF 71/291 reads (24%) | catalogued as COSV53203717; called by muse, mutect2, varscan2
- NLRC4 | c.3021T>C p.F1007= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV50875267; called by muse, mutect2, varscan2
- PCDHB4 | c.1338C>T p.N446= | Silent (SNP) | VAF 129/270 reads (48%) | catalogued as rs1273401894, COSV52021411; called by muse, mutect2, varscan2
- RD3 | c.510C>T p.S170= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65363011; called by muse, mutect2, varscan2
- TNS3 | c.2271C>T p.T757= | Silent (SNP) | VAF 71/320 reads (22%) | catalogued as rs373110561; called by muse, mutect2, varscan2
- ZNF676 | c.852C>T p.P284= (on ENST00000650058; = p.P252= on NM_001001411.3) | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs1322185228, COSV68093102; called by muse, varscan2
- AP000769.3 | chr11:65503415 ins TA | 5'Flank (INS) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
